CCDI case PBBNDK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/1855b96c-580d-4c4a-91c9-242083e43ccc

Demographics
Sex at birth: female; Vital status: Alive.

Diagnoses (1)
1. Dermatofibrosarcoma protuberans, NOS: ICD-O-3 morphology code: 8832/3; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 8.4 years (3,053 days).

Biospecimens (3 samples)
- Sample 0DD6RU: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DD6S2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DD6S3: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
